Gene-level copy-number profile of tumor specimen ALCH-B2S0-TTP1-A from ALCHEMIST case ALCH-B2S0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.3 years (18,729 days).
Specimen ALCH-B2S0-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 805fd71e-0fb8-41f7-847a-fa80a0bec4ac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2S0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/df03c8c7-f665-42c7-bcee-f3facbf0aa86

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 6,027; copy number 2: 46,076; copy number 3: 6,187; copy number 4: 79; copy number 5: 8; copy number 6: 2; copy number 7: 1; copy number 8: 4; copy number 12: 1; copy number 26: 1; copy number 34: 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:8,846,076–8,871,839, 2 genes: HMX1, AC116612.1.
- chr8:46,822,174–46,907,309, 6 genes (within-gene range 0–1): LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20.
- chr21:13,905,960–13,906,488, 1 gene: SNX18P13.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:98,954,394–98,954,972, 1 gene, copy number 6: AC022121.1.
- chr15:84,467,901–84,526,949, 6 genes, copy number 5–12 (within-gene range 3–12): Metazoa_SRP, UBE2Q2P12, AC048382.4, AC048382.3, GOLGA6L5P, AC048382.2.
- chr17:75,135,248–75,182,959, 5 genes, copy number 5: JPT1, AC022211.3, AC022211.1, Y_RNA, SUMO2.
- chr18:2,649,761–2,655,395, 2 genes, copy number 5: RNU6-340P, CBX3P2.
- chr21:43,414,483–43,479,534, 4 genes, copy number 6–34: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 6,027. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
